Gene-level copy-number profile of tumor specimen TCGA-FW-A3TU-06A from TCGA case TCGA-FW-A3TU, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 76.7 years (28,031 days).
Specimen TCGA-FW-A3TU-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.799525e6-bc70-492d-93e7-f5db3a35a7ae.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FW-A3TU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/50c7b33d-b98f-4a48-b6ff-fd76fa382064

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 351; copy number 2: 13,623; copy number 3: 6,619; copy number 4: 32,792; copy number 5: 4,309; copy number 6: 13; copy number 7: 1,391; copy number 8: 710.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FW-A3TU-06A-11D-A238-01): tumor purity 0.84, ploidy 1.85, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:140,575,788–140,898,381, 3 genes (within-gene range 0–3): AL035446.2, MIR4465, RPS3AP24.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 245. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
